Gene-level copy-number profile of tumor specimen ALCH-B2OX-TTP1-A from ALCHEMIST case ALCH-B2OX, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 52.3 years (19,110 days).
Specimen ALCH-B2OX-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 266dbf91-3955-4be4-8e03-6df0060e703b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2OX-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,233 have no estimate.
https://portal.gdc.cancer.gov/files/dc59a962-4df4-4406-804c-5ada44d52201

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 40; copy number 1: 285; copy number 2: 17,627; copy number 3: 2,480; copy number 4: 31,254; copy number 5: 1,301; copy number 6: 4,516; copy number 7: 767; copy number 8: 87; copy number 9: 10; copy number 10: 7; copy number 11: 11; copy number 13: 3; copy number 14: 2.

Homozygous deletions (total copy number 0; autosomes only): 37 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:779,840–2,331,664, 18 genes: LINC01115, LINC01939, AC113607.1, SNTG2-AS1, SNTG2, AC114808.1, AC114808.2, AC108462.1, AC105450.1, TPO, AC141930.1, AC141930.2, AC144450.1, PXDN, MYT1L, AC093390.2, AC093390.1, MYT1L-AS1.
- chr2:3,957,652–4,656,498, 4 genes: LINC01304, AC012445.1, NPM1P48, LINC01249.
- chr5:121,671,373–121,671,872, 1 gene: AC106806.2.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr10:109,680,442–109,681,041, 1 gene: XIAPP1.
- chr11:46,396,414–46,700,619, 8 genes (within-gene range 0–2): AMBRA1, AC024293.1, MIR3160-1, MIR3160-2, AC127035.1, HARBI1, ATG13, ARHGAP1.
- chr21:13,038,160–13,120,807, 4 genes: ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 33 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:29,636,486–29,826,711, 2 genes, copy number 14: AL354676.1, ME2P1.
- chr9:61,190,003–61,662,690, 11 genes, copy number 11: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA, AL935212.1.
- chr12:27,466,810–27,695,564, 6 genes, copy number 9: SMCO2, RARS1P1, PPFIBP1, AC087257.1, AC087257.2, AC009509.3.
- chr14:105,093,609–105,100,131, 2 genes, copy number 10: LINC02298, AL512356.4.
- chr14:105,620,506–105,669,843, 6 genes, copy number 9–10 (within-gene range 4–10): IGHG4, MIR8071-1, IGHG2, MIR8071-2, COPDA1, IGHGP.
- chr15:94,231,538–94,483,952, 1 gene, copy number 13 (within-gene range 4–13): MCTP2.
- chr15:94,293,537–94,600,821, 3 genes, copy number 9–13: AC135626.2, AC009432.2, AC009432.1.
- chr15:94,855,586–94,857,011, 1 gene, copy number 9 (within-gene range 6–9): AC107976.1.
- chr19:1,275,530–1,279,244, 1 gene, copy number 9: FAM174C.

Autosomal genes at a single copy (total copy number 1): 164. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
